Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CV, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CV-01A (Primary Tumor).

[page 1 of 3]
MRNA Discrepancy		☒

Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: M

Collected:

Received:

Case type: Surgical Case

Accession

DIAGNOSIS

- (A) RIGHT MODIFIED NECK DISSECTION LEVEL 2:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF TWENTY-ONE LYMPH NODES
Extracapsular extension is not identified
- (B) RIGHT NECK DISSECTION LEVEL 3:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF NINE LYMPH NODES
Extracapsular extension is not identified
- (C) RIGHT MODIFIED NECK DISSECTION LEVEL 4:
METASTATIC PAPILLARY THYROID CARCINOMA IN THREE OF EIGHT LYMPH NODES
Extracapsular extension is not identified
- (D) RIGHT MODIFIED NECK DISSECTION, LEVEL 5:
METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF SEVENTEEN LYMPH NODES
Extracapsular extension is not identified
- (E) LEFT MODIFIED NECK DISSECTION LEVEL 2
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF THREE LYMPH NODES
EXTRACAPSULAR EXTENSION IS PRESENT
- (F) LEFT MODIFIED NECK DISSECTION LEVEL 3:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF FIVE LYMPH NODES
Extracapsular extension is not identified
- (G) LEFT MODIFIED NECK DISSECTION LEVEL 4:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF SIX LYMPH NODES
Extracapsular extension is not identified
- (H) LEFT MODIFIED NECK DISSECTION LEVEL 5:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF TWENTY-FOUR LYMPH NODES
Extracapsular extension is not identified
- (I) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA, BILATERAL (LEFT: 4.0 CM, RIGHT: 1.7 CM), WITH
EXTRA-THYROIDAL EXTENSION
LYMPHOVASCULAR INVASION IS PRESENT
(See comment)
- (J) BILATERAL PARATRACHEAL AND UPPER MEDIASTINAL DISSECTION:
METASTATIC PAPILLARY THYROID CARCINOMA IN SEVEN OF TWELVE LYMPH NODES
EXTRACAPSULAR EXTENSION IS PRESENT
Focally hypercellular parathyroid gland (0.6 cm)

10/5/11
8260/3
Site: Thyroid, Nec C73.9
Carcinoma, papillary, thyroid

[page 2 of 3]
Surgical Pathology Report

DOB:
Physician:

Sex: M

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

Entire report and diagnosis completed by

COMMENT

Carcinoma in the right lobe focally extends to a cauterized tissue edge.

GROSS DESCRIPTION

(A) RIGHT MODIFIED NECK DISSECTION LEVEL 2 - An irregular fragment of fibroadipose tissue (5.0 x 2.0 x 1.0 cm). The specimen is serially sectioned and 20 lymph nodes are identified (ranging from 0.2 x 0.2 x 0.2 to 2.0 x 1.5 x 0.8 cm).

SECTION CODE: A1, six lymph nodes; A2, six lymph nodes; A3, four lymph nodes; A4, two lymph nodes; A5, one lymph node bisected; A6, one lymph node bisected.

(B) RIGHT NECK DISSECTION LEVEL 3 - An irregular fragment of fibroadipose tissue (4.0 x 2.0 x 1.0 cm). The specimen is serially sectioned and nine lymph nodes are identified ranging from (0.2 x 0.1 x 0.1 to 1.5 x 0.6 x 0.4 cm).

SECTION CODE: B1, three lymph nodes; B2, two lymph nodes; B3, three lymph nodes; B4, one lymph node.

(C) RIGHT MODIFIED NECK DISSECTION LEVEL 4 - An irregular fragment of fibroadipose tissue (5.0 x 2.5 x 1.0 cm). The specimen is serially sectioned and eight lymph nodes are identified ranging from (0.3 x 0.2 x 0.2 to 1.5 x 1.0 x 0.5 cm).

SECTION CODE: C1, four lymph nodes; C2, two lymph nodes; C3, one lymph node; C4, one lymph node bisected.

(D) RIGHT MODIFIED NECK DISSECTION, LEVEL 5 - An irregular fragment of fibroadipose tissue (7.0 x 5.0 x 1.5 cm). The specimen is serially sectioned and 17 lymph nodes are identified, ranging from (0.2 x 0.2 x 0.2 to 1.5 x 0.8 x 0.5 cm).

SECTION CODE: D1, three lymph nodes; D2, three lymph nodes; D3, three lymph nodes; D4, two lymph nodes; D5, six lymph nodes.

(E) LEFT MODIFIED NECK DISSECTION LEVEL II - A red-yellow soft tissue fragment (7.5 x 3.9 x 1.4 cm).

Within the soft tissue there are four lymph nodes ranging from (0.7 x 0.5 x 0.4 cm to 3.2 x 1.9 x 1.6 cm).

SECTION CODE: E1, two lymph nodes; E2-E5, largest lymph node serially sectioned; E6-E7, one lymph node serially sectioned.

(F) LEFT MODIFIED NECK DISSECTION LEVEL III - A yellow-red soft tissue fragment (4.7 x 3.5 x 1.2 cm).

Within the adipose tissue there are five lymph nodes ranging from (0.4 x 0.3 x 0.2 cm to 2.8 x 1.2 x 0.9 cm).

SECTION CODE: F1, one lymph node bisected; F2, one lymph node bisected; F3-F4, one lymph node serially sectioned; F5, two lymph nodes.

(G) LEFT MODIFIED NECK DISSECTION LEVEL IV - A yellow-red soft tissue fragment (5.2 x 3.4 x 0.8 cm).

Within the soft tissue there are ten lymph nodes ranging from (0.3 to 3.3 cm) in maximum dimension.

SECTION CODE: G1, three lymph nodes; G2, three lymph nodes; G3, two lymph nodes; G4, one lymph node bisected; G5, one lymph node bisected.

(H) LEFT MODIFIED NECK DISSECTION LEVEL V - A yellow-red soft tissue fragment (12.2 x 3.5 x 1.2 cm).

Within the soft tissue there are twenty-seven possible lymph nodes (0.3 to 1.0 cm) in maximum dimension.

SECTION CODE: H1, six lymph nodes; H2, six lymph nodes; H3, six lymph nodes; H4, four lymph nodes; H5, one lymph node bisected; H6, four lymph nodes.

(I) TOTAL THYROIDECTOMY - A total thyroidectomy specimen includes left thyroid (5.0 x 3.5 x 4.0 cm), fragment of skeletal muscle (5.0 x 3.0 x 0.4 cm), and right thyroid (3.5 x 3.0 x 1.5 cm). Serial section of left lobe reveals an ill-defined maroon-colored lesion (4.0 x 2.5 x 2.0 cm) with area of cyst and hemorrhage. It almost occupies entire lobe of left thyroid. Serial

[page 3 of 3]
Surgical Pathology Report

Department of Pathology

DOB:
Physician:

Sex: M

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

section of right thyroid reveals a tan, well-demarcated nodular lesion (1.7 x 1.5 x 1.0 cm) identified at middle and lower portions of thyroid. Serial section of skeletal muscle, no lesion identified. Representative sections are submitted.

INK CODE: Black - posterior surface of the thyroid.

SECTION CODE: I-1-I-6, section of lesion from superior portion of left thyroid; I-7-I-11, section of lesion from middle portion of left thyroid; I-12-I-15, representative section of lesion from inferior portion of left thyroid; I16, section of isthmus; I-17-I-20, entire serial section of lesion of right thyroid, from superior to inferior; I-21, a section of normal thyroid from right thyroid; I-22, a section of skeletal muscle.

(J) BILATERAL PARATRACHEAL AND UPPER MEDIASTINAL DISSECTION - Red-maroon irregular fragment of fibroadipose tissue, full portions of muscle attached (9.6 x 3.5 x 1.7 cm). The specimen is sectioned and 14 possible lymph nodes are found, ranging in size from 0.3 x 0.3 x 0.2 cm to 3.5 x 2.7 x 2.0 cm. The two largest lymph nodes are grossly positive.

SECTION CODE: J1, representative section of muscles; J2, four possible lymph nodes; J3, three possible lymph nodes; J4, five possible lymph nodes; J5, J6, one trisected possible lymph node (grossly positive); J7-J12, one serially sectioned possible lymph node (grossly positive).

CLINICAL HISTORY

old with neck mass, FNA, show papillary thyroid carcinoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

z. These tests have not been specifically cleared or

Released by:

Surgical Pathology Report	Page 3 of 3
File under: Pathology	

Source: NCI Genomic Data Commons file 55d03d20-c77f-4d95-871c-52dd6525368e (TCGA-EL-A3CV.E2607487-999B-4EFB-8D7E-CB419FAB9FBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).